MMRF case MMRF_1807 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/747d0455-f33f-44c3-b664-94298998e141

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.1 years (28,543 days); ISS stage: I; Days to last known disease status: 858 days (2.3 years); Days to last follow up: 858 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -48 (ECOG 1): M Protein 1.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.647 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.432 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.23 µg/mL; Lactate Dehydrogenase 1.68 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 4.18 mmol/L.
- Day 122 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.723 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 6.63 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 16.2 mmol/L.
- Day 340: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.39 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 2.53 µkat/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 11.2 mmol/L.
- Day 522 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 9.06 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 2.97 µg/mL; Hemoglobin 8.18 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 18.3 mmol/L.
- Day 627 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 2.58 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 15.5 mmol/L.
- Day 781 (ECOG 1): Hemoglobin 6.14 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 1.95 mmol/L.
- Day 858 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.78 g/L; Beta 2 Microglobulin 3.63 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.9 g/dL; Glucose 14.2 mmol/L.

Other clinical attributes
- Day -48: Weight: 67 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Multiple Myeloma.

Biospecimens (2 samples)
- Sample MMRF_1807_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -48 days.
- Sample MMRF_1807_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -48 days.
